Somatic mutation profile of tumor specimen TCGA-K4-A5RH-01A (aliquot TCGA-K4-A5RH-01A-11D-A30E-08) from TCGA case TCGA-K4-A5RH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 69.3 years (25,305 days).
Specimen TCGA-K4-A5RH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 346ab67c-0f57-4797-b526-e6cd4c1b048a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A5RH-10A (Blood Derived Normal), aliquot TCGA-K4-A5RH-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6dfadb5-8e7d-45e9-84af-479faed6417c

The open-access MAF lists 202 somatic variants for this specimen: 155 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 44, Nonsense Mutation 13, Frame Shift Del 4, Intron 2, Nonstop Mutation 1, 5'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as rs765429911, CM109595, COSV64671812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4337G>T p.R1446L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KLF4 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 66/367 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65929284; called by muse, mutect2, varscan2
- ABCA1 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as COSV66068562; called by muse, mutect2, varscan2
- ABCB5 | c.1462G>A p.D488N (on ENST00000404938 / NM_001163941.2; = p.D43N on NM_178559.6) | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV51715337; called by muse, mutect2, varscan2
- ADAMTS18 | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.051); catalogued as rs775981977, COSV51418335, COSV51419695; called by muse, mutect2, varscan2
- ADAMTS9 | c.2170T>A p.C724S | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55786008; called by muse, mutect2
- ADAMTSL1 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs780897867, COSV65894384; called by muse, mutect2
- AFG3L2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs776352499, COSV52312899; called by muse, mutect2, varscan2
- AIM2 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV63700897; called by muse, mutect2, varscan2
- AK7 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as COSV50876746; called by muse, mutect2, varscan2
- AMER1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as COSV57664168; called by muse, mutect2, varscan2
- ANKRD30A | c.523C>T p.P175S (on ENST00000611781; = p.P119S on NM_052997.2) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs879046249, COSV64605181, COSV64615803; called by muse, mutect2, varscan2
- ARHGAP29 | c.3638C>T p.S1213L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1237831137, COSV53114390; called by muse, mutect2, varscan2
- ASPHD1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs370030676; called by muse, mutect2, varscan2
- ATR | c.6535A>G p.M2179V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV63388924; called by muse, mutect2, varscan2
- BANP | c.557C>G p.S186C (on ENST00000286122; = p.S155C on NM_017869.4) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV53740283; called by muse, mutect2, varscan2
- BCCIP | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as COSV53395564; called by muse, mutect2, varscan2
- BCL7B | c.371C>A p.A124E | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV56271027; called by muse, mutect2
- BLM | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV61925699; called by muse, mutect2, varscan2
- BMI1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV64959377; called by muse, mutect2, varscan2
- C8orf37 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1323976796, COSV54413067; called by muse, mutect2, varscan2
- CARD11 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs777588257, COSV62755968, COSV62756107, COSV62757107; called by muse, mutect2, varscan2
- CEP250 | c.7051G>A p.E2351K | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV61172030; called by muse, mutect2, varscan2
- CHML | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100087402, COSV59365995; called by muse, mutect2, varscan2
- CLK2 | c.1117G>C p.E373Q (on ENST00000368361 / NM_001294339.2; = p.E372Q on NM_003993.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56946563; called by muse, mutect2, varscan2
- CNGB1 | c.2910G>A p.M970I | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs756942679, COSV51900934, COSV51902161; called by muse, mutect2, varscan2
- CUBN | c.2087A>G p.H696R | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as rs760016108, COSV64721884; called by muse, mutect2
- CYC1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 49/399 reads (12%) | catalogued as COSV100010383; called by muse, mutect2, varscan2
- CYP24A1 | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV53775718; called by muse, mutect2, varscan2
- DCAF12 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.035); catalogued as COSV63513157; called by muse, mutect2, varscan2
- DCLK2 | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV56208334; called by muse, mutect2
- DCP1A | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99587971; called by muse, mutect2, varscan2
- DDI1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1212172543, COSV56369168; called by muse, mutect2, varscan2
- DDX46 | c.2606C>G p.S869C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as COSV62800180; called by muse, mutect2
- DISC1 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54413133; called by muse, mutect2, varscan2
- DNAJC13 | c.6605A>G p.Q2202R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.042); catalogued as rs779198660, COSV53454572; called by muse, mutect2, varscan2
- DPAGT1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62614112, COSV62614795; called by muse, mutect2, varscan2
- DSTYK | c.2728A>G p.M910V | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV65687494; called by muse, mutect2, varscan2
- EIF4A2 | c.955T>G p.F319V | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56217955; called by muse, mutect2, varscan2
- EIF4G3 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs960593366, COSV51688180; called by muse, mutect2, varscan2
- ELOA3C | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 40/1136 reads (4%) | catalogued as COSV99796550; called by muse, mutect2
- EMC1 | c.2611del p.L871Ffs*25 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as COSV64346222; called by mutect2, pindel, varscan2
- EMD | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as COSV63962360; called by muse, mutect2, varscan2
- EXD3 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV59810156; called by muse, mutect2, varscan2
- FANCE | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759034838, COSV57689081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV61047655; called by muse, mutect2, varscan2
- FLNA | c.3571G>C p.A1191P | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.489); catalogued as COSV61037657, COSV61047668; called by muse, mutect2, varscan2
- FOXA3 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867687500, COSV56216885; called by muse, mutect2
- FSTL5 | c.1648G>C p.D550H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV60188219, COSV60212576; called by muse, mutect2, varscan2
- GALNS | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as COSV51939067; called by muse, mutect2, varscan2
- GATA2 | c.1338C>A p.F446L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV62003533, COSV62005669; called by muse, varscan2
- GATA2 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV62004587, COSV62005679; called by muse, varscan2
- GATA2 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM116978, COSV100351020, COSV62005686; called by muse, mutect2, varscan2
- GID4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs961266678, COSV52009580, COSV52010632; called by muse, mutect2, varscan2
- GLI2 | c.1589C>T p.A530V (on ENST00000361492 / NM_001374353.1; = p.A547V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV58046831; called by muse, mutect2, varscan2
- GLT8D1 | c.759G>C p.W253C | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56478007; called by muse, mutect2, varscan2
- GRIK2 | c.2147T>C p.V716A | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.025); catalogued as COSV59753998; called by muse, mutect2, varscan2
- GRIK3 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs142974275; called by muse, mutect2, varscan2
- GRIP2 | c.2606G>T p.R869L (on ENST00000619221; = p.R772L on NM_001080423.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.428); catalogued as rs374577398, COSV56123112; called by mutect2, varscan2
- GRXCR1 | c.148T>G p.C50G | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV67673278; called by muse, mutect2
- GYPA | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51618883, COSV51632369; called by muse, mutect2, varscan2
- HEATR1 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV63979499; called by muse, mutect2, varscan2
- HEPHL1 | c.2932C>T p.L978F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59894218; called by muse, mutect2, varscan2
- HEPHL1 | c.3022C>G p.H1008D | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59894229; called by muse, mutect2, varscan2
- HMGB2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as rs17849374, COSV56633979; called by muse, varscan2
- HYDIN | c.13507G>A p.E4503K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101125071; called by muse, mutect2, varscan2
- IRF2BP1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs201096414, COSV56193361; called by mutect2, varscan2
- IRX6 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV51861351; called by muse, mutect2, varscan2
- ITGB8 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV56008662; called by muse, mutect2, varscan2
- KIF7 | c.3595C>T p.R1199C | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as rs748917501, COSV51544256; called by muse, mutect2, varscan2
- KMT2A | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as rs868934108, COSV63281620; called by muse, mutect2, varscan2
- KMT2C | c.8439G>C p.Q2813H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.259); catalogued as COSV51470691; called by muse, mutect2, varscan2
- KNDC1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV58842151; called by muse, mutect2, varscan2
- KNTC1 | c.2827G>C p.D943H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV61082103; called by muse, mutect2, varscan2
- KPNA5 | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as rs760750928, COSV62653545; called by muse, mutect2, varscan2
- KRT85 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as rs376902194; called by muse, mutect2, varscan2
- LMNA | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV61543526; called by muse, mutect2, varscan2
- LPP | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57103921; called by muse, mutect2
- LRRC45 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs199704096, COSV60712369; called by muse, mutect2, varscan2
- MAGEC1 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1357386902, COSV53568374; called by muse, mutect2, varscan2
- MAP3K5 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369430560; called by muse, mutect2, varscan2
- MCOLN1 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV51178027; called by muse, mutect2, varscan2
- MINDY1 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 112/349 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV56498749; called by muse, mutect2, varscan2
- MN1 | c.2737G>A p.G913R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.49); catalogued as COSV56560202; called by muse, mutect2, varscan2
- MPHOSPH10 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV54906488; called by muse, mutect2, varscan2
- MYF5 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV57355838; called by muse, mutect2, varscan2
- MYO18B | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs780287472, COSV59124242; called by muse, mutect2, varscan2
- MYO5B | c.4259A>G p.E1420G | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs775700108, COSV53225099; called by muse, mutect2
- N4BP1 | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99285142; called by muse, mutect2
- NDUFAF5 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99176347; called by muse, mutect2
- NECTIN2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs553307679, COSV52978737; called by muse, mutect2, varscan2
- NKAPL | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561868233, COSV59198625; called by muse, mutect2, varscan2
- NLRP12 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60750874; called by muse, mutect2, varscan2
- NPR1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV64140536; called by muse, varscan2
- ODAM | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs747508046, COSV101258048; called by muse, mutect2, varscan2
- OGDH | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56048712, COSV56053761, COSV99758179; called by muse, mutect2, varscan2
- PCSK6 | c.2635C>G p.P879A | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.994); catalogued as COSV61856558; called by muse, mutect2
- PDZRN4 | c.1474G>A p.E492K (on ENST00000402685 / NM_001164595.2; = p.E234K on NM_013377.4) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as COSV54209336; called by muse, mutect2, varscan2
- PHF21A | c.941G>A p.R314K (on ENST00000418153 / NM_001101802.3; = p.R315K on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.977); catalogued as COSV57657360; called by muse, mutect2, varscan2
- PIK3R1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV57134659; called by muse, mutect2, varscan2
- PLEKHM3 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV66815305; called by muse, mutect2, varscan2
- PML | c.500C>G p.A167G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs1047320957, COSV51450277; called by muse, mutect2, varscan2
- POLR3C | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV57907935; called by muse, varscan2
- POLR3C | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV57907925; called by muse, varscan2
- PPFIA2 | c.3106C>T p.Q1036* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100333273; called by muse, mutect2, varscan2
- PPP1R9B | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100380697; called by muse, mutect2
- PPP6R2 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53296002; called by muse, mutect2, varscan2
- PRDM1 | c.1604C>G p.S535* | Nonsense Mutation (SNP) | VAF 24/110 reads (22%) | catalogued as COSV100958757; called by muse, mutect2, varscan2
- PRPF3 | c.2051G>C p.*684Sext*67 | Nonstop Mutation (SNP) | VAF 38/164 reads (23%) | catalogued as COSV61394971; called by muse, mutect2, varscan2
- RABEP1 | c.2424G>C p.Q808H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52586711; called by muse, varscan2
- RBL1 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60331503; called by muse, mutect2, varscan2
- RELB | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV55511764; called by muse, mutect2, varscan2
- RIOK2 | c.1546G>C p.A516P | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.445); catalogued as rs1302582890, COSV51613923; called by muse, mutect2, varscan2
- RNF216 | c.1353G>T p.K451N (on ENST00000425013 / NM_207116.3; = p.K508N on NM_207111.4) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV66288878, COSV66291755; called by muse, mutect2, varscan2
- RPTN | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV60168196; called by muse, mutect2, varscan2
- RPTN | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 212/1925 reads (11%) | catalogued as COSV100285471; called by muse, varscan2
- RPTN | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 216/1832 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV60168200; called by muse, varscan2
- RPTN | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 203/1892 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60168203; called by muse, mutect2, varscan2
- RPTN | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 78/719 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV60168207; called by muse, mutect2, varscan2
- RPUSD4 | c.26C>G p.S9W | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV53599820; called by muse, mutect2, varscan2
- RYBP | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV101523298; called by muse, mutect2
- SEPTIN1 | c.305A>G p.Q102R (on ENST00000321367; = p.Q55R on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as COSV100363061; called by mutect2, varscan2
- SIMC1 | c.1603C>T p.Q535* (on ENST00000443967 / NM_001308196.1; = p.Q120* on NM_198567.5) | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100365478; called by muse, mutect2, varscan2
- SIRPG | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs527643862, COSV53808185; called by muse, mutect2, varscan2
- SLCO3A1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV59233818; called by muse, mutect2, varscan2
- SMARCC2 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57221624; called by muse, mutect2, varscan2
- SMURF1 | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV63158761; called by muse, mutect2, varscan2
- SNX31 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780032494, COSV61264111; called by muse, mutect2, varscan2
- SOCS6 | c.611A>T p.H204L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV67546811; called by muse, mutect2, varscan2
- SPATA31D1 | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.336); catalogued as COSV61198609; called by muse, mutect2, varscan2
- SPEN | c.7199C>A p.S2400Y | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.054); catalogued as COSV65365082; called by muse, mutect2, varscan2
- STRIP2 | c.1851C>G p.I617M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV50806138; called by muse, mutect2, varscan2
- SYBU | c.1579G>A p.D527N (on ENST00000276646 / NM_001099754.2; = p.D526N on NM_017786.6) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52620920; called by muse, mutect2, varscan2
- SYT3 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58897377; called by muse, mutect2, varscan2
- TMEM200C | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as rs564765632, COSV67309831; called by muse, mutect2, varscan2
- TOX3 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54870340; called by muse, mutect2, varscan2
- TP53 | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TREML1 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58295243; called by muse, mutect2, varscan2
- TRIP13 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV51320924; called by muse, mutect2
- TSHZ3 | c.474C>G p.S158R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV53677032; called by muse, mutect2, varscan2
- TTF2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs926315013, COSV65633183; called by muse, mutect2, varscan2
- WASF2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV71006190; called by muse, mutect2, varscan2
- XAGE5 | c.22T>A p.Y8N | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV63568088; called by muse, mutect2, varscan2
- ZNF346 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.806); catalogued as COSV56157482; called by muse, mutect2, varscan2
- ZNF429 | c.131-2A>G p.X44_splice | Splice Site (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100641888; called by muse, mutect2
- ZNF441 | c.1622G>A p.R541K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.144); catalogued as COSV63540400; called by muse, mutect2, varscan2
- ZSCAN10 | c.643G>A p.D215N (on ENST00000252463; = p.D270N on NM_032805.3) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52969424; called by muse, mutect2, varscan2
- C5 | c.3542del p.P1181Qfs*32 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- CKM | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.75); called by muse, mutect2
- FCGBP | c.7300G>A p.E2434K | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GGNBP2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- RB1 | c.1255dup p.V419Gfs*9 | Frame Shift Ins (INS) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- RUSC2 | c.3634del p.R1212Gfs*18 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by mutect2, pindel
- ZNF85 | c.677del p.G226Efs*53 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- ADAM11 | c.2133C>T p.I711= | Silent (SNP) | VAF 98/299 reads (33%) | catalogued as COSV52348146; called by muse, mutect2, varscan2
- ADAMTS9 | c.2169T>G p.L723= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV55786019; called by muse, mutect2
- AGO2 | c.1314G>A p.R438= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as rs1320238120, COSV55045529; called by muse, mutect2, varscan2
- ALAS2 | c.576C>T p.S192= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs780568189, COSV58192155; called by muse, mutect2, varscan2
- BLM | c.3231G>A p.V1077= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV61924135, COSV61925695; called by muse, mutect2, varscan2
- C20orf141 | c.297C>A p.L99= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV63028345; called by muse, mutect2
- CD177 | c.393G>A p.L131= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as rs759363398, COSV100946010, COSV65121931; called by muse, mutect2, varscan2
- CTNNA2 | c.1749A>G p.P583= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV58165733; called by muse, mutect2, varscan2
- DSCAM | c.858G>A p.S286= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs375148161, COSV68025734; called by muse, mutect2
- FPR2 | c.756C>T p.I252= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV60673841; called by muse, mutect2, varscan2
- HFE | c.927C>G p.V309= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV58513626; called by muse, mutect2, varscan2
- HMGB2 | c.549G>A p.K183= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs1376126330, COSV56633989; called by muse, varscan2
- IL16 | c.2793G>A p.Q931= (on ENST00000302987 / NM_172217.5; = p.Q230= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV57266212; called by muse, mutect2
- KRTAP10-1 | c.603C>A p.P201= | Silent (SNP) | VAF 104/331 reads (31%) | catalogued as COSV59956483, COSV59971044; called by muse, mutect2, varscan2
- MEGF6 | c.3315C>G p.L1105= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV53892673; called by muse, mutect2, varscan2
- MTARC2 | c.375C>T p.F125= | Silent (SNP) | VAF 44/196 reads (22%) | catalogued as COSV63766076; called by muse, mutect2, varscan2
- MTUS2 | c.1056A>G p.A352= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV70918787; called by muse, mutect2
- MXRA5 | c.3279C>T p.I1093= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV54242912; called by muse, mutect2, varscan2
- MYO5C | c.2106C>T p.L702= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV55909499, COSV99955188; called by muse, mutect2, varscan2
- NPR1 | c.609G>T p.L203= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100903746; called by muse, mutect2
- NPR1 | c.819G>C p.L273= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV64142338; called by muse, varscan2
- PALD1 | c.2145G>A p.L715= | Silent (SNP) | VAF 37/280 reads (13%) | catalogued as COSV54976447; called by muse, mutect2, varscan2
- PCDH15 | c.4689G>A p.L1563= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV57354505; called by muse, mutect2, varscan2
- PLCB4 | c.3369G>A p.K1123= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV53810200; called by muse, mutect2, varscan2
- PPP6R2 | c.1030C>T p.L344= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV53296023; called by muse, mutect2, varscan2
- RIMBP3 | c.3186G>C p.R1062= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- RNF6 | c.354G>A p.R118= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV60419782; called by muse, mutect2, varscan2
- RPTN | c.180C>G p.L60= | Silent (SNP) | VAF 30/239 reads (13%) | catalogued as COSV60166961, COSV60168213; called by muse, mutect2, varscan2
- RPTN | c.132C>A p.I44= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV60166439, COSV60168217; called by muse, mutect2, varscan2
- RSPH6A | c.1347C>T p.I449= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV55573802; called by muse, mutect2, varscan2
- RTP4 | c.456C>A p.A152= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV52018768; called by muse, mutect2, varscan2
- S100A1 | c.147G>A p.Q49= | Silent (SNP) | VAF 194/662 reads (29%) | catalogued as COSV52680591; called by muse, varscan2
- S100A13 | c.18G>A p.L6= | Silent (SNP) | VAF 41/279 reads (15%) | catalogued as COSV52680583, COSV52681329; called by muse, mutect2, varscan2
- SEMG2 | c.1098G>A p.Q366= | Silent (SNP) | VAF 41/189 reads (22%) | catalogued as COSV65647731; called by muse, mutect2, varscan2
- SERPINB6 | c.294G>A p.V98= (on ENST00000612421 / NM_001271823.2; = p.V79= on NM_004568.6) | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV59566541; called by muse, mutect2, varscan2
- SIDT1 | c.2364C>T p.F788= | Silent (SNP) | VAF 56/257 reads (22%) | catalogued as rs150661858, COSV53499161; called by muse, mutect2, varscan2
- SLC22A6 | c.1078C>T p.L360= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV64560542, COSV64560623; called by muse, mutect2, varscan2
- SMOX | c.513C>T p.F171= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as COSV53866497; called by muse, mutect2, varscan2
- STAM | c.1362G>A p.Q454= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as COSV66351810; called by muse, mutect2, varscan2
- THAP12 | c.1833C>T p.V611= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as COSV52609671; called by muse, mutect2, varscan2
- TPM3 | c.213G>A p.K71= | Silent (SNP) | VAF 81/193 reads (42%) | catalogued as COSV55137897, COSV55138032; called by muse, mutect2, varscan2
- TRIM41 | c.960G>C p.L320= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV59320720; called by muse, mutect2, varscan2
- TTBK2 | c.3576C>T p.P1192= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV51168392; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1071T>C p.Y357= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as rs960626242, COSV56273639; called by muse, mutect2, varscan2
- DIABLO | c.-54C>T | 5'UTR (SNP) | VAF 4/19 reads (21%) | catalogued as rs1377267503, COSV99928205; called by muse, mutect2
- GGNBP1 | n.846+928C>T | Intron (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- MGAM | c.4618+8636C>G | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as COSV72075129; called by muse, mutect2, varscan2
